TARGET case TARGET-40-NAAWHJ — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/63fb709b-d8d9-59f9-a0b0-c26726563e6f

Biospecimens (1 sample)
- Sample TARGET-40-NAAWHJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
